Surgical pathology report (de-identified scan), TCGA case TCGA-UD-AAC5, project TCGA-MESO (Mesothelioma), tissue source site  University of Western Australia, specimen TCGA-UD-AAC5-01A (Primary Tumor).

[page 1 of 2]
Patient Results

Anatomical Pathology results - Performed from

M

istopathology

At least 1 Final Result

Histopathology

Final

PATIENT
ADDRESS

SEX
D.O.B.

:
:
:
:
: M
:

LAB. NO.

DOCTOR
WARD
REQUEST DATE
DATE RECEIVED
CONSULTANT

:
:
:
:
:
:

SPECIMEN:

- A. Bronchial lymph node
- B. Mediastinal lymph node
- C. Extrapleural pneumonectomy
- D. Thymic lymph node

CLINICAL :

Extrapleural pneumonectomy for mesothelioma. Submitted bronchial, mediastinal, thymic lymph nodes and pericardial fluid. Superior part of specimen sent for research and anteromedial part re-attached (resected separately).

MACROSCOPIC:

- A. Two dark tan/black lobulated pieces of tissue each 9 x 7 x 6mm and 7 x 5 x 4mm. The larger specimen is bisected.
- B. A lobulated tan/grey piece of tissue, 15 x 10 x 8mm with surrounding blood clot. The specimen is bisected.

BLOCK KEY:

1:node, 2:blood clot
C. The specimen consists of a 1464g (post-fixation) left extrapleural pneumonectomy specimen (250 x 230 x 90mm) consisting of lung, 145mm (anterior/posterior) x 40mm (medial/lateral) x 165mm, parietal pleura, pericardium (105 x 95 x 5mm) and hemi-diaphragm (185 x 80 x 25 to 8mm). The apical, anterior, lateral and posterior parietal pleural surfaces are grossly thickened and exhibit subtle diffuse firm pale nodulation. The medial parietal pleural surface above the hilum also shows similar appearances. Multiple foci of small whitish tumour nodules are present within the inner aspect of the parietal pericardium, extending over an area of 65 x 55mm. There is a defect in the anterolateral pleural wall, 70 x 35mm in area, which most likely represents specimen taken for research prior to receipt. There are eight anthracotic hilar nodes, ranging in size from 15 x 6 x 5mm to 7 x 4 x 4mm, of which only the smallest shows macroscopic involvement by tumour.

The specimen is serially sliced transversely into multiple slices from apex to hemi-diaphragm, revealing firm, rind-like cream/white tumour encasing the entire circumference of the parietal pleura. In areas, there is fusion of the parietal and visceral pleura with a large loculated effusion present laterally. Tumour extends into the interlobar septa and into the subpleural lung parenchyma to a maximum depth of 17mm. There is extensive involvement of mediastinal fat as demonstrated by intersecting bridges of firm white tumour. Tumour lies in close proximity to the anterior and posterior pericardial resection margins as well as the medial, lateral, anterior and posterior diaphragmatic resection margins. Photographs taken.

BLOCK KEY:

1:bronchial line of resection, 2-5:hilar lymph nodes, 6:hilar lymph node, metastatic tumour, 7:anterior pericardium resection margin, 8:posterior pericardium resection margin, 9:anterior diaphragm resection margin, 10:posterior diaphragm resection margin, 11:medial diaphragm resection margin, 12:lateral diaphragm resection margin, 13:additional hilar nodes, 14,15:lateral parietal pleura, 16:parietal and visceral pleura with diaphragm, 17-19:medial pleura, 20-22:visceral pleura (lateral, involving lung), 23,24:tumour and mediastinal fat, 25-27:tumour and lung, 28:tumour and lateral pleura, 29:non-neoplastic lung, 30: additional tumour, 31 & 32:tumour internal pericardial surface.

D. Fatty tissue, 20 x 15 x 7mm within which is an anthracotic lymph node, 13 x 7 x 6mm. There appears to be no macroscopic tumour involvement. The specimen is bisected.

ICD-O-3
Mesothelioma, epithelioid, malignant 9852/3
Site: Pleura N65 C38.4
9/11/29/14

Requested by:

Printed from:

[page 2 of 2]
Patient Results

Anatomical Pathology results - Performed from

M

Histopathology

At least 1 Final Result

MICROSCOPIC:

A. The sections show a lymph node laden with histiocytes containing carbon pigment. Within the subcapsular sinus, there is one small focus of metastatic mesothelioma, less than 1mm, with focal extra capsular extension to a distance of less than 0.5mm.

B. The sections show shows a lymph node with one small focus, 1.5mm, of metastatic malignant mesothelioma.

C. Multiple sections of the left extrapleural pneumonectomy were taken, including the various resection margins from anterior and posterior pericardium, anterior, posterior, lateral and medial diaphragm, parietal pleura and mediastinal fat. The sections confirm malignant mesothelioma exhibiting predominantly an epithelial growth pattern with a very small component (5%) of sarcomatous pattern. The vast majority of the tumour is characterised by pavement-like sheets of large cells often exhibiting a microcystic growth pattern with focal necrosis. There is abundant pale basophilic material, confirmed to be hyaluronate on an Alcian blue/hyaluronidase stain. The malignant cells possess monotonous, round to oval to mildly pleomorphic vesicular nuclei, prominent nucleoli and abundant, often vacuolated cytoplasm. In focal areas the cells exhibit a spindled morphology, intermixed with moderate amounts of dense collagen. Lymphovascular space invasion is noted.

There is extensive involvement of all parietal pleural resection margins. Tumour lies close to the anterior pericardial resection margin, as well as the anterior, posterior, medial and lateral diaphragmatic resection margins. There is subpleural extension into lung and extension to the internal surface of the pericardium. The sections also confirm invasion of the mediastinal fat. The bronchial resection margin is clear of tumour and there is no invasion of the bronchial tree at the hilum (described macroscopically). Of eight hilar lymph nodes retrieved, one small lymph node shows near complete replacement by metastatic tumour with extracapsular extension to a distance of 0.5mm.

D. The sections show a lymph node with abundant histiocytes containing carbon pigment. There is no evidence of micrometastasis identified by light microscopy.

CONCLUSION:

A. Bronchial lymph node: Micrometastasis, less than 1mm, of metastatic mesothelioma, with focal extracapsular extension.

B. Mediastinal lymph node: Micrometastasis, 1.5mm, of malignant mesothelioma.

C. Extrapleural pneumonectomy:

1. Extensive involvement by malignant mesothelioma, predominantly of epithelial pattern, with focal (5 % or less) sarcomatous pattern.
2. Tumour lies focally close to anterior pericardial resection margin and anterior, posterior, medial and lateral diaphragmatic resection margins. There is subpleural invasion of the lung parenchyma and extension to the internal surface of the pericardium. Involvement beyond the parietal pleural margin is extensive with invasion into mediastinal fat. Bronchial resection margin is clear of tumour.
3. Of eight hilar lymph nodes, one is positive with focal extracapsular extension (1/8).

D. Thymic lymph node: Negative for malignancy, no micrometastases.

REGISTRAR:

PATHOLOGIST:

DOCTOR REVIEWING:

DATED:

ELECTRONICALLY VALIDATED:

Requested by:

Printed from:

Page: 2 of 3

Source: NCI Genomic Data Commons file da10027b-7cf9-4932-ac7b-dc1164be03f3 (TCGA-UD-AAC5.5BB63340-2A48-4ACB-A6D0-D8DF68A058B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).